Somatic mutation profile of tumor specimen C3N-04693-01 (aliquot CPT0293800006) from CPTAC case C3N-04693, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.5 years (19,913 days).
Specimen C3N-04693-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1b54008-64f7-4de4-9a06-18c814437aa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04693-32 (Blood Derived Normal), aliquot CPT0293830004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc072bd5-6960-49bb-9409-cdc0544e12a0

The open-access MAF lists 71 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Intron 8, Frame Shift Del 2, 3'UTR 2, 5'Flank 2, 5'UTR 2, RNA 1, 3'Flank 1, In Frame Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 84/376 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGDIB | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 87/369 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1042106739, COSV56762404; called by muse, mutect2, varscan2
- CCN4 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as rs1362674638; called by muse, mutect2, varscan2
- FAM90A14P | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 373/3074 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs748469151; called by muse, mutect2, varscan2
- FKBP4 | c.110_112del p.I37del | In Frame Del (DEL) | VAF 48/143 reads (34%) | catalogued as rs1240318695; called by pindel, varscan2
- GAS2L3 | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.233); catalogued as COSV99903244; called by muse, mutect2, varscan2
- GCC1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 132/440 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs777111161, COSV58461754; called by muse, mutect2, varscan2
- HDGFL3 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1384525474; called by muse, mutect2, varscan2
- KRTAP10-7 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 264/818 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100170027; called by muse, varscan2
- MGA | c.4214A>G p.Q1405R | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs756456538; called by muse, mutect2, varscan2
- NF1 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 161/440 reads (37%) | catalogued as CM981380, COSV100646956, COSV62202351; called by muse, mutect2, varscan2
- NF1 | c.4977_4980del p.K1661Gfs*36 (on ENST00000358273 / NM_001042492.3; = p.K1640Gfs*36 on NM_000267.3) | Frame Shift Del (DEL) | VAF 117/420 reads (28%) | catalogued as rs1085307459; called by mutect2, pindel, varscan2
- NXPE1 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs78257939; called by muse, mutect2, varscan2
- NYAP2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.212); catalogued as rs1363261078, COSV56006854; called by muse, mutect2, varscan2
- OR5K3 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101051611; called by muse, mutect2, varscan2
- SLC26A4 | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 154/561 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as CM050320; called by muse, mutect2, varscan2
- SLC9C1 | c.271A>T p.T91S | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV59886461; called by muse, mutect2, varscan2
- SOX2 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 248/705 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV57622905; called by muse, mutect2, varscan2
- TCIRG1 | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 235/616 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV55834438; called by muse, mutect2, varscan2
- TRPV5 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 104/383 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs373410726, COSV54684276; called by muse, mutect2, varscan2
- U2AF2 | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV100454029, COSV58276374; called by muse, mutect2, varscan2
- ZNF695 | c.1507C>A p.H503N | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.156); catalogued as COSV60585016; called by mutect2, varscan2
- ZNF799 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs780448774, COSV70122781; called by muse, mutect2, varscan2
- BRWD1 | c.1245-1G>A p.X415_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- CREB1 | c.815C>T p.P272L (on ENST00000432329 / NM_134442.5; = p.P258L on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 172/533 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- DNAH14 | c.9046C>A p.H3016N | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated, low confidence (0.34); called by muse, mutect2, varscan2
- EFCAB2 | c.669_671+1del | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by pindel, varscan2
- ENTPD7 | c.1011A>T p.R337S | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.425); called by muse, varscan2
- GPRASP2 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- HDAC2 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KALRN | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 241/701 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, varscan2
- KIAA1210 | c.911A>G p.E304G | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAT2A | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- MYO15A | c.7331C>G p.P2444R | Missense Mutation (SNP) | VAF 204/684 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NCKAP5 | c.1526A>G p.D509G | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PGR | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 114/367 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPM1L | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPT2 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 148/452 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTCHD4 | c.1884G>T p.K628N | Missense Mutation (SNP) | VAF 111/424 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- RYR1 | c.3572G>A p.C1191Y | Missense Mutation (SNP) | VAF 204/585 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC22A23 | c.2032G>A p.A678T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.01); called by muse, varscan2
- SLC40A1 | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 135/402 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SV2A | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF354B | c.945A>G p.I315M | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BRWD3 | c.1545G>T p.A515= | Silent (SNP) | VAF 111/380 reads (29%) | called by muse, mutect2, varscan2
- CDH16 | c.1248G>A p.L416= | Silent (SNP) | VAF 154/374 reads (41%) | called by muse, mutect2, varscan2
- GIPR | c.195C>T p.F65= | Silent (SNP) | VAF 276/825 reads (33%) | called by muse, mutect2, varscan2
- GOT1L1 | c.351G>A p.Q117= | Silent (SNP) | VAF 112/428 reads (26%) | catalogued as rs776749648; called by muse, mutect2, varscan2
- KLHDC7B | c.1107C>T p.A369= (on ENST00000395676; = p.A1010= on NM_138433.5) | Silent (SNP) | VAF 194/628 reads (31%) | called by muse, mutect2, varscan2
- KLKB1 | c.933T>C p.F311= | Silent (SNP) | VAF 13/263 reads (5%) | called by muse, mutect2
- LARS1 | c.828A>G p.P276= (on ENST00000394434 / NM_020117.11; = p.P249= on NM_016460.3) | Silent (SNP) | VAF 74/219 reads (34%) | called by muse, mutect2, varscan2
- MYO10 | c.5709C>T p.V1903= | Silent (SNP) | VAF 127/353 reads (36%) | catalogued as rs750091573; called by muse, mutect2, varscan2
- OTUD7A | c.2796G>A p.R932= (on ENST00000307050 / NM_001382637.1; = p.R925= on NM_130901.3) | Silent (SNP) | VAF 20/56 reads (36%) | called by mutect2, varscan2
- SLC19A3 | c.135C>T p.N45= | Silent (SNP) | VAF 69/207 reads (33%) | called by muse, mutect2, varscan2
- SMIM20 | c.126C>T p.P42= | Silent (SNP) | VAF 89/317 reads (28%) | catalogued as rs746810457; called by muse, mutect2, varscan2
- AC005400.1 | n.87-20738A>G | Intron (SNP) | VAF 112/421 reads (27%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506328 C>T | 3'Flank (SNP) | VAF 9/26 reads (35%) | catalogued as rs757241166; called by muse, mutect2, varscan2
- CCL4L2 | c.191+87C>T | Intron (SNP) | VAF 47/186 reads (25%) | catalogued as rs1266430858; called by muse, mutect2, varscan2
- CEP250 | c.1572-673C>T | Intron (SNP) | VAF 48/189 reads (25%) | catalogued as rs1156965488, COSV100698892; called by muse, mutect2, varscan2
- COL6A2 | c.*5G>A | 3'UTR (SNP) | VAF 127/394 reads (32%) | catalogued as rs377195134, CR161896; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2, varscan2
- CPT2 | c.1645+26C>T | Intron (SNP) | VAF 39/112 reads (35%) | catalogued as rs1317717892; called by muse, mutect2, varscan2
- FOXP2 | c.*2783T>G | 3'UTR (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- GAB3 | c.-7G>A | 5'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- GNAS | chr20:58889165 C>T | 5'Flank (SNP) | VAF 89/227 reads (39%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.158A>T | RNA (SNP) | VAF 216/651 reads (33%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.327+243G>A | Intron (SNP) | VAF 88/229 reads (38%) | called by muse, mutect2, varscan2
- SERINC5 | c.1238+2392_1238+2393delinsG | Intron (DEL) | VAF 79/502 reads (16%) | called by pindel, varscan2*
- SERPINB13 | c.-50G>T | 5'UTR (SNP) | VAF 41/181 reads (23%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.707-21G>A | Intron (SNP) | VAF 55/217 reads (25%) | catalogued as rs373608717; called by muse, mutect2, varscan2
- TOMM7 | c.103+448G>A | Intron (SNP) | VAF 28/174 reads (16%) | catalogued as rs1171209682; called by muse, mutect2, varscan2
- ZNF48 | chr16:30395357 A>C | 5'Flank (SNP) | VAF 99/275 reads (36%) | catalogued as rs1169200445; called by muse, mutect2, varscan2
